Surgical pathology report (de-identified scan), TCGA case TCGA-HT-7873, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Case Western - St Joes, specimen TCGA-HT-7873-01B (Primary Tumor).

Pathology Report for Subject

Diagnosis:

Oligoastrocytoma, WHO grade II

- MIB-labeling index = 6.1%

Microscopic Description:

Sections demonstrate a markedly hypercellular glial neoplasm that diffusely infiltrates the parenchyma. The majority of the tumor cells have an astrocytoma phenotype, but a significant minority show either poorly formed paranuclear halos or a microgemistocytic phenotype, consistent with oligodendroglioma differentiation. Atypia is generally mild, but many moderately atypical nuclei are present. Only rare mitotic figures are identified. Microvascular proliferation is not seen. MIB-labeling immunoreactivity varies throughout the tumor. In the most proliferative areas, the labeling index of 6.1% is calculated. This is an intermediate level of proliferative activity. Although it does not warrant definitive classification as grade III, anaplastic, it is worrisome for aggressive behavior.

Source: NCI Genomic Data Commons file 3b496629-6895-48c5-8993-00791ba5c8c2 (TCGA-HT-7873.0EFA1CBB-8B95-4B63-94BD-3E8829316A90.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).